Somatic mutation profile of tumor specimen BA2037D (aliquot aq-BA2037D) from BEATAML1.0 case 2182, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with inv(3)(q21q26.2) or t(3;3)(q21;q26.2), RPN1-EVI1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 34.3 years (12,531 days).
Specimen BA2037D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8a24c73-bea9-4118-8197-e90051869204.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2001D (Solid Tissue Normal), aliquot aq-BA2001D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad0dda7c-8df4-4160-a1a7-6657a7c4b74b

The open-access MAF lists 6 somatic variants for this specimen: 2 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, In Frame Del 1, Missense Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZAN | c.1553C>T p.T518M | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as rs747613197, COSV61805163; called by muse, mutect2
- CCNH | c.770_772del p.N257_L258delinsI | In Frame Del (DEL) | VAF 51/134 reads (38%) | called by mutect2, varscan2
- FRMD4A | c.1890C>T p.S630= | Silent (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- GPR37L1 | c.480C>T p.Y160= | Silent (SNP) | VAF 25/57 reads (44%) | called by muse, mutect2, varscan2
- OR7C1 | c.282T>C p.Y94= | Silent (SNP) | VAF 22/57 reads (39%) | called by muse, mutect2, varscan2
- KCNC3 | chr19:50333875 C>T | 5'Flank (SNP) | VAF 12/26 reads (46%) | called by mutect2, varscan2
